Somatic mutation profile of tumor specimen C3L-01286-01 (aliquot CPT0086940009) from CPTAC case C3L-01286, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.7 years (21,429 days).
Specimen C3L-01286-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12653299-5fc9-4f51-855c-e961df153f4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01286-31 (Blood Derived Normal), aliquot CPT0087450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fdf5382-8fe0-4356-a076-ec8084f6cecf

The open-access MAF lists 106 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Intron 5, 3'UTR 4, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, 5'Flank 3, Splice Region 2, In Frame Del 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs750194005, COSV66583891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD24 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs758342016; called by muse, varscan2
- CCDC42 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs781345210; called by muse, mutect2, varscan2
- CDH22 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as rs926295661; called by muse, mutect2, varscan2
- CEP295 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57349476; called by muse, mutect2, varscan2
- CPLX2 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1334772726; called by muse, mutect2, varscan2
- DAAM1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419113038; called by muse, mutect2, varscan2
- EIF2B2 | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 196/407 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as CM152520, COSV56720257; called by muse, mutect2, varscan2
- HGFAC | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs577434025, COSV66977323; called by muse, mutect2, varscan2
- KCNH7 | c.1820G>C p.G607A | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169469826, COSV59790106; called by muse, mutect2, varscan2
- KIAA0319L | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs41310436, COSV57843171, COSV57844099; called by muse, mutect2, varscan2
- KRT2 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 100/449 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1330514030; called by muse, mutect2, varscan2
- OR2L2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs753145578, COSV63551776; called by muse, mutect2, varscan2
- OR52N1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.859); catalogued as COSV57693368, COSV57693885; called by muse, mutect2, varscan2
- PAGR1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV56188506; called by muse, mutect2, varscan2
- PATL1 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as COSV55693559; called by muse, mutect2, varscan2
- PCNX3 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758077741, COSV63136005; called by muse, mutect2, varscan2
- PCSK5 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406686253, COSV65084371; called by muse, mutect2, varscan2
- QSER1 | c.1886C>T p.S629L (on ENST00000399302; = p.S758L on NM_001076786.3) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV67899550; called by muse, mutect2, varscan2
- REST | c.1823T>C p.M608T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1387308478; called by muse, mutect2, varscan2
- SETD2 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV57434480, COSV57448778; called by muse, mutect2, varscan2
- ST18 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs141556653; called by muse, mutect2, varscan2
- TERT | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 171/413 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1554042981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC33 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | catalogued as rs374271035; called by muse, mutect2, varscan2
- TTLL10 | c.477C>A p.F159L (on ENST00000379289 / NM_001130045.2; = p.F86L on NM_153254.3) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV64959736; called by muse, mutect2, varscan2
- ABCA10 | c.4533+2T>A p.X1511_splice | Splice Site (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- ACAA1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 114/185 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AKAP6 | c.1944A>C p.E648D | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ANKS1B | c.2261T>A p.V754D | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BRD8 | c.653G>T p.S218I (on ENST00000254900 / NM_139199.2; = p.S291I on NM_006696.4) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by mutect2, varscan2
- C16orf89 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN9 | c.402G>A p.Q134= | Splice Region (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- CEP290 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2567G>A p.C856Y | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DMD | c.2243C>A p.A748E | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DPCD | c.247_259del p.L83Afs*14 | Frame Shift Del (DEL) | VAF 43/216 reads (20%) | called by pindel, varscan2
- E2F1 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFCAB5 | c.1275G>C p.R425S | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EFR3B | c.1654del p.L552Sfs*49 | Frame Shift Del (DEL) | VAF 43/259 reads (17%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EML5 | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FLT1 | c.1184dup p.T396Nfs*2 | Frame Shift Ins (INS) | VAF 66/268 reads (25%) | called by mutect2, pindel, varscan2
- FYB1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); called by muse, mutect2
- FZD3 | c.1553+2T>G p.X518_splice | Splice Site (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- HEY1 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 270/456 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IL6ST | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- JUP | c.848_853delinsG p.K283Sfs*37 | Frame Shift Del (DEL) | VAF 72/470 reads (15%) | called by pindel, varscan2*
- KIAA1614 | c.2105T>A p.F702Y | Missense Mutation (SNP) | VAF 218/371 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KIAA1841 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF1A | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KISS1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 320/565 reads (57%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP1 | c.2344G>A p.E782K (on ENST00000404816 / NM_206943.4; = p.E456K on NM_000627.4) | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MAP3K19 | c.3535G>T p.E1179* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- MGAT3 | c.773C>G p.T258S | Missense Mutation (SNP) | VAF 76/124 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIPAL3 | c.93+7del | Splice Region (DEL) | VAF 40/168 reads (24%) | called by mutect2, pindel, varscan2
- NOP53 | c.1374-2A>T p.X458_splice | Splice Site (SNP) | VAF 63/269 reads (23%) | called by muse, mutect2, varscan2
- NPIPB2 | c.491A>T p.K164I (on ENST00000399147; = p.K24I on NM_001355514.1) | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR9G4 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PHF20 | c.2580G>T p.R860S | Missense Mutation (SNP) | VAF 332/482 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLXNC1 | c.1900T>C p.C634R | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNC1 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- S100A10 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2
- SEH1L | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC17A7 | c.435_440del p.R145_F147delinsS | In Frame Del (DEL) | VAF 66/145 reads (46%) | called by mutect2, pindel, varscan2
- SPARCL1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRMT5 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13B | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WDR41 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR91 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB3 | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM5 | c.1390_1404del p.E464_Q468del | In Frame Del (DEL) | VAF 29/157 reads (18%) | called by mutect2, pindel, varscan2
- ZNF114 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.33); called by muse, mutect2
- ALMS1 | c.1977G>A p.T659= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as rs201316401; ClinVar: likely benign; called by muse, mutect2, varscan2
- B3GALT1 | c.198T>C p.L66= | Silent (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- CACNA1H | c.5685C>T p.D1895= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as rs1463806903, COSV52356542; called by muse, mutect2, varscan2
- CPA5 | c.681G>T p.L227= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as COSV62568748; called by muse, mutect2, varscan2
- CTAGE15 | c.1257G>A p.V419= | Silent (SNP) | VAF 101/608 reads (17%) | catalogued as rs1455939379; called by muse, mutect2, varscan2
- GNPTAB | c.2466C>G p.T822= | Silent (SNP) | VAF 41/147 reads (28%) | called by muse, mutect2, varscan2
- GPAT2 | c.1188C>T p.G396= | Silent (SNP) | VAF 109/268 reads (41%) | catalogued as rs746992961; called by muse, mutect2, varscan2
- HCRTR1 | c.999C>T p.R333= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs200222372; called by muse, mutect2, varscan2
- ITIH1 | c.1275G>A p.R425= | Silent (SNP) | VAF 57/104 reads (55%) | called by muse, mutect2, varscan2
- LHX5 | c.33C>T p.P11= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as rs897376357; called by muse, mutect2, varscan2
- MCM10 | c.1389G>A p.G463= (on ENST00000484800 / NM_182751.3; = p.G462= on NM_018518.5) | Silent (SNP) | VAF 75/213 reads (35%) | called by muse, mutect2, varscan2
- METTL25 | c.1668C>T p.P556= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV50261609; called by muse, mutect2, varscan2
- PER1 | c.3609G>A p.V1203= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1113G>A p.L371= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- VNN2 | c.1287C>T p.F429= | Silent (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- WDR41 | c.1128C>T p.S376= | Silent (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- ZBTB46 | c.84C>T p.G28= | Silent (SNP) | VAF 248/347 reads (71%) | catalogued as rs368634130; called by muse, mutect2, varscan2
- ZNF777 | c.1017C>T p.R339= | Silent (SNP) | VAF 36/251 reads (14%) | catalogued as rs373973043; called by muse, mutect2, varscan2
- CRISPLD2 | c.240+31C>A | Intron (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- DENND2C | c.*18A>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs201437846; called by mutect2, varscan2
- E2F6 | c.164-1628C>A | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598843 C>T | 5'Flank (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2
- MAPK8IP1P2 | n.261G>A | RNA (SNP) | VAF 7/334 reads (2%) | catalogued as rs953779573; called by muse, mutect2
- MIR124-2 | chr8:64378189 G>A | 5'Flank (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- MMP9 | c.1902-16C>G | Intron (SNP) | VAF 63/552 reads (11%) | called by muse, mutect2, varscan2
- RAX2 | c.*19C>A | 3'UTR (SNP) | VAF 48/184 reads (26%) | catalogued as rs1391595572; called by muse, mutect2, varscan2
- RECQL4 | c.-41T>C | 5'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as rs1564813478; called by muse, mutect2, varscan2
- SCFD1 | c.613+604C>T | Intron (SNP) | VAF 50/188 reads (27%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100990169 A>G | 5'Flank (SNP) | VAF 28/88 reads (32%) | catalogued as rs745746858; called by muse, mutect2, varscan2
- SOX5 | c.*1010C>A | 3'UTR (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- SPATA7 | c.190+37T>G | Intron (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- TMEM134 | c.*30_*39del | 3'UTR (DEL) | VAF 49/232 reads (21%) | called by mutect2, pindel, varscan2
- TPM1 | chr15:63069969 G>A | 3'Flank (SNP) | VAF 84/228 reads (37%) | catalogued as rs747553234; called by muse, mutect2, varscan2
